Gene-level copy-number profile of tumor specimen TCGA-ED-A66Y-01A from TCGA case TCGA-ED-A66Y, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 51.5 years (18,797 days).
Specimen TCGA-ED-A66Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.37e8f09e-fa99-4747-a90e-813360ca3bdd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ED-A66Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b8a3291a-f63f-42a0-b485-3e9540613dfb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 2: 3,729; copy number 3: 12,027; copy number 4: 20,801; copy number 5: 18,585; copy number 6: 2,735; copy number 7: 1,770; copy number 8: 141.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ED-A66Y-01A-11D-A30U-01): tumor purity 0.89, ploidy 3.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:54,901,509–56,651,600, 23 genes (within-gene range 0–2): CCDC68, MAP1LC3P, LINC01929, RNA5SP459, TCF4, TCF4-AS1, MIR4529, TCF4-AS2, AC022031.2, RPL21P126, LINC01415, AC022031.1, AC027584.1, LINC01416, AC009271.1, AC006305.1, AC009271.2, LINC01905, AC006305.2, SNORA73, LINC01539, AC006305.3, TXNL1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
